Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4881, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4881-01A (Primary Tumor).

Normal Sample ID. [REDACTED]

Pathology Report

DIAGNOSIS

(A) RIGHT KIDNEY:

RENAL CELL CARCINOMA (10.0 CM MAXIMUM DIMENSION), CONVENTIONAL TYPE
(90% CLEAR CELLS,
10% EOSINOPHILIC CELLS), FUHRMAN NUCLEAR GRADE 3, INVASIVE INTO RENAL
PELVICALICEAL
SYSTEM. (SEE COMMENT)

Margins of resection free of tumor.

COMMENT

The renal cell carcinoma in the right kidney invades into the renal pelvis. The perinephric adipose tissue, renal sinus adipose tissue and renal vein are free of tumor. Multifocal tumor necrosis is present. The non-neoplastic renal parenchyma shows interstitial inflammation and hemorrhage in renal tubules.

GROSS DESCRIPTION

(A) RIGHT KIDNEY, RULE OUT TCC - A radical nephrectomy specimen with surrounding perinephric fat (12.5 x 9.0 x 6.0 cm, overall measurement) with attached 8.5 cm long segment of ureter (0.3 cm in diameter).

Cut sections reveal a variegated yellow-red tumor (measuring 10.0 x 6.0 x 6.0 cm), which forms a 5.0 x 4.5 x 3.0 cm mass protruding into the renal pelvis. The tumor does not appear to invade into the renal sinus, perinephric adipose tissue, or the renal vein.

The uninvolved renal parenchyma has foci of linear hemorrhages in the cortico-medullary junction.

INK CODE: Black - perinephric fat margin.

SECTION CODE: A1, A2, sections of tumor submitted for frozen section; A3, hemorrhage in uninvolved renal parenchyma; A4, artery, vein and ureter margin; A5-A7, tumor in relation to renal pelvis and kidney parenchyma; A8, A9, representative sections of tumor protruding into renal pelvis; A10, tumor with kidney parenchyma; A11, tumor with adjacent renal sinus; A12, and A13, tumor with perinephric fat margin.

[REDACTED]

CLINICAL HISTORY

Right renal mass.

SNOMED CODES

T-71000, M-83123

[REDACTED]

Source: NCI Genomic Data Commons file 899da67d-5d7e-4a71-b06c-a975c910015a (TCGA-CJ-4881.36725C29-F964-4AB9-92E6-776D85380D62.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).